Somatic mutation profile of tumor specimen TCGA-CH-5750-01A (aliquot TCGA-CH-5750-01A-11D-1576-08) from TCGA case TCGA-CH-5750, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 72.2 years (26,389 days).
Specimen TCGA-CH-5750-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a4742c8-63ef-41cd-b1da-fb9601f0f638.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5750-10A (Blood Derived Normal), aliquot TCGA-CH-5750-10A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/086fc0e5-3a31-4893-89bd-fd8585ed0b22

The open-access MAF lists 38 somatic variants for this specimen: 30 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 24, Silent 8, Frame Shift Del 3, Frame Shift Ins 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC4 | c.587A>G p.N196S | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs200675964, COSV65315693; called by muse, mutect2, varscan2
- ADAM9 | c.1200C>A p.N400K | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.062); catalogued as COSV65959925, COSV65961275; called by muse, mutect2
- ANLN | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.808); catalogued as COSV56077877; called by muse, varscan2
- BRPF1 | c.3548A>G p.N1183S | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57352804; called by muse, mutect2, varscan2
- CNTNAP5 | c.2377G>A p.V793I | Missense Mutation (SNP) | VAF 76/213 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs751028037, COSV70476456; called by muse, mutect2, varscan2
- DLX5 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.265); catalogued as rs868027286; called by muse, mutect2
- EFCAB6 | c.2350C>T p.R784C | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756978843, COSV53067729; called by muse, mutect2, varscan2
- ENGASE | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56136432; called by muse, mutect2, varscan2
- FAM171A1 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.942); catalogued as rs774474168, COSV65317769; called by muse, varscan2
- GH2 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 87/473 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as rs377217606; called by muse, mutect2, varscan2
- GSTA2 | c.455A>T p.K152M | Missense Mutation (SNP) | VAF 71/230 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV72415260; called by muse, mutect2, varscan2
- MSH6 | c.1147A>G p.R383G | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV52283829; called by muse, mutect2, varscan2
- PCDHGA2 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1389707234, COSV53989059; called by muse, mutect2
- PHTF2 | c.25A>G p.I9V | Missense Mutation (SNP) | VAF 80/226 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as rs778356622, COSV50333400; called by muse, mutect2, varscan2
- PIWIL1 | c.1734T>G p.D578E | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.065); catalogued as COSV55349483; called by muse, mutect2, varscan2
- PKN2 | c.232dup p.S78Kfs*14 | Frame Shift Ins (INS) | VAF 36/104 reads (35%) | catalogued as rs1335792632; called by mutect2, varscan2
- PLCH2 | c.553G>T p.G185W | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53946493; called by muse, mutect2, varscan2
- PRPF8 | c.5615T>G p.L1872R | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59265466; called by muse, mutect2, varscan2
- RANBP17 | c.1623T>G p.C541W | Missense Mutation (SNP) | VAF 19/266 reads (7%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV66653713; called by muse, mutect2
- RBFOX1 | c.676+2T>G p.X226_splice | Splice Site (SNP) | VAF 39/259 reads (15%) | catalogued as COSV60968756; called by muse, mutect2, varscan2
- SIM1 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs763972030, COSV53490592; called by muse, mutect2, varscan2
- SLITRK3 | c.605A>G p.D202G | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53850785; called by muse, mutect2, varscan2
- SOX17 | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52024815; called by muse, mutect2, varscan2
- SPHKAP | c.4702C>T p.P1568S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.976); catalogued as COSV60887410; called by muse, varscan2
- TTN | c.48109G>A p.V16037I (on ENST00000591111; = p.V8613I on NM_003319.4) | Missense Mutation (SNP) | VAF 113/286 reads (40%) | PolyPhen probably damaging (0.99); catalogued as COSV60198215; called by muse, mutect2, varscan2
- ZDBF2 | c.1687C>T p.R563W | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs771789452, COSV65621821; called by muse, mutect2, varscan2
- C19orf53 | c.261del p.A89Qfs*94 | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | called by mutect2, pindel, varscan2
- EPB41L4A | c.21_22del p.P8Gfs*12 | Frame Shift Del (DEL) | VAF 16/78 reads (21%) | called by mutect2, pindel, varscan2
- HERC2 | c.11594del p.C3865Lfs*44 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, varscan2
- INTU | c.684_685dup p.D229Vfs*7 | Frame Shift Ins (INS) | VAF 51/173 reads (29%) | called by mutect2, pindel, varscan2
- HIBADH | c.873C>T p.D291= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV55315325; called by muse, mutect2, varscan2
- KIF12 | c.852G>T p.L284= (on ENST00000640217; = p.L146= on NM_138424.1) | Silent (SNP) | VAF 38/220 reads (17%) | catalogued as COSV65117797; called by muse, mutect2, varscan2
- MAGEC3 | c.1494C>T p.F498= | Silent (SNP) | VAF 11/200 reads (6%) | catalogued as rs1233995692, COSV53575710, COSV53577836; called by muse, mutect2
- NKAPL | c.243C>T p.Y81= | Silent (SNP) | VAF 39/123 reads (32%) | catalogued as COSV59198153; called by muse, mutect2, varscan2
- P4HA2 | c.1419G>T p.G473= | Silent (SNP) | VAF 38/129 reads (29%) | catalogued as COSV51327968; called by muse, mutect2, varscan2
- REG1A | c.237C>T p.A79= | Silent (SNP) | VAF 76/198 reads (38%) | catalogued as rs1262823078, COSV52070549; called by muse, mutect2, varscan2
- S1PR2 | c.285T>A p.S95= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV58485662; called by muse, mutect2, varscan2
- TCOF1 | c.1740C>T p.P580= (on ENST00000377797 / NM_001135243.1; = p.P503= on NM_000356.4) | Silent (SNP) | VAF 54/220 reads (25%) | catalogued as COSV60351230; called by mutect2, varscan2
